Gene-level copy-number profile of tumor specimen TCGA-KB-A93H-01A from TCGA case TCGA-KB-A93H, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 79.3 years (28,966 days).
Specimen TCGA-KB-A93H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.b905bcbc-8e7b-4400-a084-06485b6adecd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KB-A93H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/93c3cf10-8765-4f0b-b266-38132ff1034b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 15; copy number 2: 263; copy number 3: 11,359; copy number 4: 18,721; copy number 5: 7,074; copy number 6: 9,907; copy number 7: 4,901; copy number 8: 3,294; copy number 9: 2,403; copy number 10: 566; copy number 11: 547; copy number 12: 14; copy number 13: 736; copy number 149: 1; copy number 157: 5; copy number 218: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KB-A93H-01A-11D-A396-01): tumor purity 0.6, ploidy 4.99, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr6:147,508,690–148,018,985, 4 genes (within-gene range 0–5): SAMD5, AL033504.1, AL365271.1, AL445123.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,275 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:53,490,148–53,811,952, 4 genes, copy number 149–218 (within-gene range 3–218): RN7SKP218, AC009468.2, AC009468.1, LINC01446.
- chr7:54,933,699–55,255,635, 5 genes, copy number 157 (within-gene range 6–157): AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1.
- chr7:63,011,463–67,362,950, 197 genes, copy number 9 (broad region; genes not listed).
- chr8:105,287,830–110,632,394, 54 genes, copy number 9 (within-gene range 6–9): AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1.
- chr8:127,072,694–127,227,541, 1 gene, copy number 9 (within-gene range 6–9): CASC19.
- chr8:127,253,213–127,257,630, 1 gene, copy number 9: AC018714.2.
- chr8:127,292,233–127,292,440, 1 gene, copy number 9: AC018714.1.
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 9–10 (broad region; genes not listed).
- chr18:21,529,284–24,397,880, 67 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr18:55,589,904–57,491,298, 29 genes, copy number 9 (within-gene range 7–9): AC022031.2, RPL21P126, LINC01415, AC022031.1, AC027584.1, LINC01416, AC009271.1, AC006305.1, AC009271.2, LINC01905, AC006305.2, SNORA73, LINC01539, AC006305.3, TXNL1, WDR7, Y_RNA, AC012301.1, U3, WDR7-OT1, AC012301.2, LINC-ROR, AC100775.1, BOD1L2, LINC02565, RNU6-737P, ST8SIA3, AC090340.1, ONECUT2.
- chr18:58,044,226–80,247,514, 336 genes, copy number 9–12 (within-gene range 7–12) (broad region; genes not listed).
- chr19:49,067,418–58,605,223, 736 genes, copy number 13 (within-gene range 3–13) (broad region; genes not listed).
- chr20:87,250–17,682,295, 326 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:17,956,979–18,059,188, 1 gene, copy number 9 (within-gene range 6–9): OVOL2.
- chr20:17,969,018–64,313,132, 1,126 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
